Somatic mutation profile of tumor specimen TARGET-40-PANSEN-01A (aliquot TARGET-40-PANSEN-01A-01D) from TARGET case TARGET-40-PANSEN, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.3 years (5,234 days).
Specimen TARGET-40-PANSEN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09613cff-9259-4768-8362-b2162389d93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANSEN-10A (Blood Derived Normal), aliquot TARGET-40-PANSEN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b21d8232-2149-4875-a60f-d3647e3a0f76

The open-access MAF lists 88 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Intron 7, 5'UTR 3, 3'UTR 2, Nonsense Mutation 2, Translation Start Site 1, IGR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SKI | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 142/852 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907303, CM129800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1S | c.3631G>A p.G1211R | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs1174808695; called by muse, mutect2, varscan2
- CEP131 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV53953171; called by muse, mutect2, varscan2
- CFAP52 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | catalogued as rs1369063623; called by muse, varscan2
- DNAH8 | c.8143C>T p.R2715C | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs367945482; called by muse, mutect2, varscan2
- DNAI4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/171 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs1461525708; called by muse, mutect2, varscan2
- IRF2BP1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs1319216953; called by muse, mutect2
- LILRA4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV52492620; called by muse, mutect2
- LONRF2 | c.1987T>C p.W663R | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145208665; called by muse, mutect2
- NDN | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1262150615; called by muse, mutect2
- ODF2L | c.1450G>A p.E484K (on ENST00000317336; = p.E455K on NM_020729.3) | Missense Mutation (SNP) | VAF 90/499 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99644804; called by muse, varscan2
- PCDHA10 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 47/1171 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs782208845, COSV56532873; called by muse, mutect2
- PHOX2B | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV56928681; called by muse, mutect2
- PIGU | c.220C>G p.H74D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV54166388; called by muse, mutect2
- PRG4 | c.1594A>G p.T532A | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV63354865; called by mutect2, varscan2
- REN | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766783107; called by muse, mutect2, varscan2
- SLC5A4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs1232731554; called by muse, mutect2, varscan2
- SLC5A9 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 30/596 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1044519316; called by muse, mutect2
- SYTL1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as rs1487852807; called by muse, mutect2
- TIMM44 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs750582664; called by muse, mutect2, varscan2
- TMEM145 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV56623856; called by muse, mutect2
- ZC3H14 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1207878391; called by muse, mutect2
- ZNF79 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1564239703; called by muse, mutect2, varscan2
- ZSCAN1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1429955815; called by muse, mutect2
- CDT1 | c.570C>G p.Y190* | Nonsense Mutation (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- CRB2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); called by muse, mutect2
- CSMD2 | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2
- DECR2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- DEF6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- EED | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2
- FCRLA | c.207C>G p.C69W (on ENST00000367959; = p.C46W on NM_032738.4) | Missense Mutation (SNP) | VAF 32/815 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- FER1L6 | c.3671C>A p.A1224D | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KRT31 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 47/1462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMB1 | c.5329C>G p.Q1777E | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRIG3 | c.637A>C p.K213Q | Missense Mutation (SNP) | VAF 225/447 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MYH7 | c.5455G>A p.V1819M | Missense Mutation (SNP) | VAF 79/1105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- NOA1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- OR11A1 | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- OSBPL9 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKD1L1 | c.3877G>A p.D1293N | Missense Mutation (SNP) | VAF 53/753 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.248); called by muse, mutect2
- PPP2R5E | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ROR1 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDC3 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHPK | c.1412G>C p.R471T | Missense Mutation (SNP) | VAF 99/1139 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- SIGMAR1 | c.388T>G p.S130A | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2
- SLBP | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC44A1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 54/864 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.355); called by muse, mutect2
- SLCO1B1 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO2B1 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 54/698 reads (8%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31A1 | c.1505A>G p.H502R | Missense Mutation (SNP) | VAF 304/639 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAM2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 28/807 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBR4 | c.5249G>A p.R1750K | Missense Mutation (SNP) | VAF 142/407 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ULK2 | c.2403C>A p.S801R | Missense Mutation (SNP) | VAF 40/744 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ZFP36 | c.682C>T p.P228S (on ENST00000594442; = p.P222S on NM_003407.5) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2
- ZFYVE26 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2
- ZNF205 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF497 | c.1128C>G p.H376Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK1 | c.4377C>T p.G1459= | Silent (SNP) | VAF 94/536 reads (18%) | called by muse, mutect2, varscan2
- CCSER2 | c.696C>T p.F232= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- CFAP52 | c.237C>T p.I79= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as rs199772187; ClinVar: likely benign; called by muse, varscan2
- CLIP2 | c.474C>G p.A158= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as rs1554732709; called by muse, mutect2
- FRMPD4 | c.1917G>A p.L639= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- INTS3 | c.1902C>G p.V634= | Silent (SNP) | VAF 36/539 reads (7%) | called by muse, mutect2
- KIAA2013 | c.1089C>T p.N363= | Silent (SNP) | VAF 154/1394 reads (11%) | called by muse, mutect2, varscan2
- PFKFB2 | c.1356C>T p.N452= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1140G>A p.L380= | Silent (SNP) | VAF 35/356 reads (10%) | called by muse, mutect2, varscan2
- PPP1R7 | c.288A>G p.V96= | Silent (SNP) | VAF 46/417 reads (11%) | catalogued as rs747249804; called by muse, mutect2, varscan2
- SALL3 | c.1155C>T p.N385= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV73306295; called by muse, mutect2
- SLC12A3 | c.2019C>T p.I673= | Silent (SNP) | VAF 45/423 reads (11%) | catalogued as rs758071801, COSV52638056; called by muse, mutect2, varscan2
- SLC25A22 | c.525C>T p.R175= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs368124957; called by muse, varscan2
- TMEM255B | c.348G>A p.P116= | Silent (SNP) | VAF 24/271 reads (9%) | catalogued as rs541950367, COSV64704811; called by muse, mutect2
- TREM1 | c.357C>T p.P119= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV55149509; called by muse, mutect2, varscan2
- TTC3 | c.5721G>A p.K1907= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- ZNF135 | c.702G>C p.R234= (on ENST00000313434 / NM_001289401.2; = p.R246= on NM_003436.4) | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- CLDN7 | c.*11C>T | 3'UTR (SNP) | VAF 36/273 reads (13%) | called by muse, mutect2, varscan2
- CNN3 | c.-17C>T | 5'UTR (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- DYNLRB1 | c.3+16G>A | Intron (SNP) | VAF 155/222 reads (70%) | catalogued as rs202095087; called by muse, mutect2, varscan2
- EPHA4 | c.*21A>G | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- FEM1AP2 | n.1123G>A | RNA (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- GLI1 | c.535-87G>A | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- GSTM1 | c.178-57G>A | Intron (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- KRTAP5-3 | c.-1C>T | 5'UTR (SNP) | VAF 66/383 reads (17%) | called by muse, mutect2, varscan2
- MARK4 | c.1877+214C>A | Intron (SNP) | VAF 151/533 reads (28%) | called by muse, mutect2, varscan2
- REC8 | c.1451+15G>A | Intron (SNP) | VAF 120/502 reads (24%) | catalogued as rs762582823; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1579G>A | Intron (SNP) | VAF 50/237 reads (21%) | called by muse, mutect2, varscan2
- SNRPD3 | c.-6G>A | 5'UTR (SNP) | VAF 76/569 reads (13%) | called by muse, mutect2, varscan2
- SPAG7 | c.242+25G>A | Intron (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- Unknown | chr7:55699012 C>T | IGR (SNP) | VAF 22/177 reads (12%) | catalogued as rs267601546; called by muse, mutect2
